Gene-level copy-number profile of tumor specimen TCGA-24-1842-01A from TCGA case TCGA-24-1842, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 49.9 years (18,227 days).
Specimen TCGA-24-1842-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.8b89f646-2877-40ee-b91a-2bb8f843d9e9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1842-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c26ae28b-4a6e-472c-b4cf-36646261d677

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,223; copy number 2: 11,168; copy number 3: 17,520; copy number 4: 18,116; copy number 5: 5,537; copy number 6: 3,921; copy number 7: 1,245; copy number 8: 154; copy number 9: 240; copy number 10: 263; copy number 11: 248; copy number 12: 79; copy number 15: 39; copy number 20: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1842-01A-01D-0577-01): tumor purity 0.68, ploidy 3.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 921 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:174,011,856–178,108,339, 101 genes, copy number 9–11 (within-gene range 4–11) (broad region; genes not listed).
- chr2:211,375,717–213,152,427, 13 genes, copy number 9 (within-gene range 6–9): ERBB4, RNA5SP119, MTND2P23, MTCO1P46, MIR548F2, AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2, IKZF2.
- chr2:236,567,787–237,085,838, 5 genes, copy number 9 (within-gene range 6–9): ACKR3, AC084030.1, AC012063.1, RNU6-1051P, AC105760.1.
- chr3:22,381,819–24,103,238, 20 genes, copy number 9: HMGB1P5, AC092421.1, AC114477.1, RANP7, SALL4P5, RPL24P7, UBE2E2-AS1, UBE2E2, Y_RNA, AC121251.1, RNU6-922P, RNU6-788P, UBE2E1-AS1, UBE2E1, ARL4AP4, NKIRAS1, RPL15, NR1D2, LINC00691, NPM1P23.
- chr3:83,384,445–86,125,287, 14 genes, copy number 10: AC023503.1, AC092825.1, SRRM1P2, AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1.
- chr3:112,696,908–115,721,490, 62 genes, copy number 9 (broad region; genes not listed).
- chr3:115,837,870–115,838,159, 1 gene, copy number 9: RN7SL815P.
- chr3:145,523,538–148,987,668, 45 genes, copy number 9–11: LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1, AC092957.1, LINC02010, RNU6-505P, RPL21P71, ZIC4, ZIC4-AS1, ZIC1, NPM1P28, AC092925.1, AC092958.1, AC092958.4, LINC02032, AC092958.3, AC092958.2, AC025566.1, HNRNPA1P20, LINC02045, LINC02046, AC069410.1, RPL38P1, AGTR1, CPB1, HMGB1P30, AC092979.1, CPA3, AC092979.2, UBQLN4P1.
- chr3:149,738,472–152,841,439, 68 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr3:164,670,878–165,846,519, 7 genes, copy number 10 (within-gene range 6–10): LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322.
- chr3:167,239,843–173,336,965, 108 genes, copy number 11–20 (within-gene range 6–20) (broad region; genes not listed).
- chr4:68,877,626–72,148,067, 79 genes, copy number 12 (within-gene range 6–12) (broad region; genes not listed).
- chr7:52,165,235–56,675,086, 103 genes, copy number 9–11 (broad region; genes not listed).
- chr7:64,369,241–68,036,917, 118 genes, copy number 10 (broad region; genes not listed).
- chr8:73,277,364–75,566,834, 50 genes, copy number 9–10: PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1, STAU2, AC018620.1, AC100784.1, VENTXP6, AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G.
- chr11:29,713,909–35,818,007, 106 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr21:19,046,310–21,543,329, 21 genes, copy number 10 (within-gene range 8–10): AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1.

Autosomal genes at a single copy (total copy number 1): 870. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
